Somatic mutation profile of tumor specimen TCGA-EB-A42Z-01A (aliquot TCGA-EB-A42Z-01A-12D-A24R-08) from TCGA case TCGA-EB-A42Z, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.7 years (18,157 days).
Specimen TCGA-EB-A42Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 743c2dca-02a1-4c73-949c-be879293671a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A42Z-10A (Blood Derived Normal), aliquot TCGA-EB-A42Z-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90b125b9-f1ec-4973-b80e-53770db902a3

The open-access MAF lists 126 somatic variants for this specimen: 82 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 42, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AMPD3 | c.1625C>T p.P542L (on ENST00000396553 / NM_001025389.2; = p.P551L on NM_000480.3) | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs139950075; called by muse, mutect2, varscan2
- ARHGEF28 | c.4645G>A p.E1549K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.591); catalogued as rs1466652323, COSV55256752; called by muse, mutect2, varscan2
- ARIH2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62704846; called by muse, mutect2, varscan2
- ARL13B | c.487-2A>C p.X163_splice (on ENST00000394222 / NM_001174150.2; = p.X56_splice on NM_144996.4) | Splice Site (SNP) | VAF 27/67 reads (40%) | catalogued as COSV57398398; called by muse, varscan2
- ARMC5 | c.2630G>T p.R877L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV51656649; called by muse, mutect2, varscan2
- ASXL2 | c.3857C>T p.P1286L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV55459141, COSV99711842; called by muse, mutect2, varscan2
- ATP8B4 | c.2768G>A p.G923E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs867448784, COSV99463112; called by muse, mutect2, varscan2
- CAPN13 | c.1854G>C p.R618S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54431045; called by muse, mutect2, varscan2
- CARD10 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs866057374, COSV52656761; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CDPF1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53078683; called by muse, mutect2, varscan2
- CKAP4 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV65172505; called by muse, mutect2, varscan2
- CYP2C18 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53672342; called by muse, mutect2, varscan2
- CYP2C8 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV64877235; called by muse, mutect2, varscan2
- CYP2C9 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 145/265 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53248910; called by muse, mutect2, varscan2
- DNAH10 | c.12878C>T p.S4293L (on ENST00000409039; = p.S4232L on NM_207437.3) | Missense Mutation (SNP) | VAF 69/93 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs748316604, COSV53019881; called by muse, mutect2, varscan2
- DOCK3 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56522511; called by muse, mutect2, varscan2
- DYNC2H1 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 15/21 reads (71%) | catalogued as rs867798254, COSV62094614; called by muse, mutect2, varscan2
- EMILIN2 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54422643; called by muse, mutect2, varscan2
- EML3 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1396686393, COSV53872170; called by muse, mutect2, varscan2
- ERN2 | c.2346G>A p.W782* | Nonsense Mutation (SNP) | VAF 208/495 reads (42%) | catalogued as rs1226637252, COSV55622194; called by muse, mutect2, varscan2
- EXO5 | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56415762; called by muse, mutect2, varscan2
- FAM227B | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54811283; called by muse, mutect2, varscan2
- FAM90A1 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.904); catalogued as COSV56712175; called by muse, mutect2, varscan2
- FAR1 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV61384891, COSV61385492; called by muse, mutect2, varscan2
- FBXO40 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57524171; called by muse, mutect2, varscan2
- FCRL3 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs759615906, COSV63841490; called by muse, mutect2, varscan2
- FMO3 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768393243, COSV63007308; called by muse, mutect2, varscan2
- GABRE | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 139/165 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs757646574, COSV64818761, COSV64819994, COSV64821147; called by muse, mutect2, varscan2
- GLI1 | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as COSV57362286; called by muse, mutect2, varscan2
- ITPRID2 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV100237891, COSV57469709; called by muse, mutect2, varscan2
- KALRN | c.1967G>A p.W656* | Nonsense Mutation (SNP) | VAF 30/61 reads (49%) | catalogued as COSV53764938; called by muse, mutect2, varscan2
- KANSL3 | c.995T>A p.V332E | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62617622; called by muse, mutect2, varscan2
- KCNT1 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53681668; called by muse, mutect2, varscan2
- LIMCH1 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58284181, COSV58286175; called by muse, mutect2, varscan2
- LRP1B | c.11587G>A p.G3863R | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101259655, COSV67222351; called by muse, mutect2, varscan2
- MGAM | c.5180A>C p.H1727P | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.43); catalogued as COSV72074696; called by muse, mutect2, varscan2
- MKRN2 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV50105213; called by muse, mutect2, varscan2
- MSR1 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 66/86 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50512224; called by muse, mutect2, varscan2
- MUC16 | c.32795G>A p.G10932E | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV67467576; called by muse, mutect2, varscan2
- MYO18B | c.6427C>T p.P2143S | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV59134889; called by muse, mutect2, varscan2
- NCAN | c.3412T>C p.F1138L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.166); catalogued as COSV53051482; called by muse, mutect2, varscan2
- NCKAP1 | c.3129G>T p.L1043F | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV62941244; called by muse, mutect2, varscan2
- NLRP13 | c.908C>A p.P303Q | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61621794; called by muse, mutect2, varscan2
- NUP188 | c.4276C>A p.H1426N | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV65340448; called by muse, mutect2, varscan2
- OR4C16 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV58942090; called by muse, mutect2, varscan2
- OR8B4 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV62069757; called by muse, mutect2, varscan2
- PACS2 | c.1049C>G p.P350R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV57652885, COSV57657711; called by muse, mutect2, varscan2
- PARM1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs375803068; called by muse, mutect2, varscan2
- PCDHB6 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 173/394 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV50698707; called by muse, mutect2, varscan2
- PDGFRA | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs143344944, COSV57265372; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- PLCB1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs866425965, COSV100569417, COSV62051786; called by muse, mutect2, varscan2
- PLPP2 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54120748; called by muse, mutect2, varscan2
- PRSS22 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV50721310; called by muse, mutect2, varscan2
- RAB33B | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV59777398; called by muse, mutect2, varscan2
- RASGRP4 | c.510C>T p.L170= | Splice Region (SNP) | VAF 23/50 reads (46%) | catalogued as COSV53095566; called by muse, mutect2, varscan2
- RBP1 | c.307G>A p.E103K (on ENST00000619087 / NM_001365940.2; = p.E165K on NM_002899.5) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV51676730; called by muse, mutect2, varscan2
- RP1L1 | c.6043G>A p.E2015K | Missense Mutation (SNP) | VAF 215/294 reads (73%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.448); catalogued as rs184873506, COSV101222878, COSV66752938; called by muse, mutect2, varscan2
- SCAF1 | c.2299G>C p.G767R | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV62183394; called by muse, mutect2, varscan2
- SCN9A | c.5410G>A p.D1804N (on ENST00000303354; = p.D1793N on NM_002977.3) | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV57610548; called by muse, mutect2, varscan2
- SEPTIN3 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV52170864, COSV52172343; called by muse, mutect2, varscan2
- SERPINA7 | c.875G>A p.W292* | Nonsense Mutation (SNP) | VAF 141/172 reads (82%) | catalogued as rs902678899, COSV59665870; called by muse, mutect2, varscan2
- SIGLEC7 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as COSV58314618; called by muse, mutect2, varscan2
- SLC44A1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs141353650; called by muse, mutect2, varscan2
- SLC4A5 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.862); catalogued as rs761652021, COSV61027805; called by muse, mutect2, varscan2
- SLCO5A1 | c.1587T>G p.I529M | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52659713; called by muse, mutect2, varscan2
- SNCAIP | c.2521G>A p.G841S | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV54410683; called by muse, mutect2, varscan2
- SPG11 | c.2340T>A p.N780K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55995179; called by muse, mutect2, varscan2
- SPSB4 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as COSV60147463; called by muse, mutect2, varscan2
- STXBP5L | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV56510578; called by muse, mutect2, varscan2
- SUN5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 108/267 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV62181257; called by muse, mutect2, varscan2
- THNSL1 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64479343; called by muse, mutect2, varscan2
- TIMD4 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257003344, COSV50855573; called by muse, mutect2, varscan2
- TRIM54 | c.901C>T p.R301W (on ENST00000380075 / NM_187841.3; = p.R343W on NM_032546.4) | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs762051439, COSV51990019; called by muse, mutect2, varscan2
- UTRN | c.9119A>T p.D3040V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV62304350; called by muse, mutect2, varscan2
- ZCWPW1 | c.631+1G>A p.X211_splice | Splice Site (SNP) | VAF 97/194 reads (50%) | catalogued as rs774275324, COSV61249078; called by muse, mutect2, varscan2
- ZHX2 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV58713357; called by muse, mutect2, varscan2
- ZNF343 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs187274947; called by muse, mutect2, varscan2
- ZNF578 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV69736540, COSV69736542; called by muse, varscan2
- ZNF835 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV73379454; called by muse, mutect2, varscan2
- USP42 | c.3901_3913del p.E1301Tfs*23 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- AP3B2 | c.2490C>T p.P830= (on ENST00000261722; = p.P824= on NM_004644.5) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV55609828; called by muse, mutect2, varscan2
- APEX2 | c.255C>T p.F85= | Silent (SNP) | VAF 35/38 reads (92%) | catalogued as COSV66624011; called by muse, mutect2, varscan2
- ATP8B4 | c.2769G>A p.G923= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs751561190, COSV99463110; called by muse, mutect2, varscan2
- CASR | c.801C>T p.I267= | Silent (SNP) | VAF 84/196 reads (43%) | catalogued as rs148721982, COSV56134615; called by muse, mutect2, varscan2
- CDH8 | c.1635C>T p.F545= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV54868473; called by muse, mutect2, varscan2
- CMKLR1 | c.156C>T p.F52= (on ENST00000312143 / NM_001142344.2; = p.F50= on NM_004072.3) | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as rs751530283, COSV56435954, COSV56438441; called by muse, mutect2, varscan2
- COL14A1 | c.2631G>A p.V877= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as COSV52854977; called by muse, mutect2, varscan2
- CPN2 | c.153G>A p.T51= | Silent (SNP) | VAF 54/159 reads (34%) | catalogued as rs778326304, COSV60469536; called by muse, mutect2, varscan2
- CYP11A1 | c.1497C>T p.L499= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as rs376403897, COSV51432226; called by muse, mutect2, varscan2
- DDX42 | c.2763C>T p.D921= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as rs576068219, COSV63790184; called by muse, mutect2, varscan2
- EIF3E | c.241C>T p.L81= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as rs202033451; called by muse, mutect2, varscan2
- F10 | c.705C>T p.I235= | Silent (SNP) | VAF 66/180 reads (37%) | catalogued as rs137995645; called by muse, mutect2, varscan2
- GNGT1 | c.171C>T p.I57= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV50352795; called by muse, mutect2, varscan2
- HS3ST6 | c.531C>T p.I177= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs757277149, COSV53534633; called by muse, mutect2, varscan2
- IQSEC1 | c.414C>T p.A138= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV56224127; called by muse, mutect2, varscan2
- KEL | c.1335G>A p.A445= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs751855900, COSV100786892, COSV62335129; called by muse, mutect2, varscan2
- KIF21B | c.3081G>A p.L1027= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV59758225; called by muse, mutect2, varscan2
- KRT3 | c.1411C>T p.L471= | Silent (SNP) | VAF 56/88 reads (64%) | catalogued as rs1159852256, COSV58815707; called by muse, mutect2, varscan2
- L1TD1 | c.1623C>T p.P541= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV63133512; called by muse, mutect2, varscan2
- LTN1 | c.2613G>A p.L871= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV63733868; called by muse, mutect2, varscan2
- MTMR3 | c.2679C>T p.P893= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV60304565; called by muse, mutect2, varscan2
- MUC20 | c.261C>T p.S87= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100290842; called by mutect2, varscan2
- MYH1 | c.2910G>A p.K970= | Silent (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- NHSL2 | c.1650C>T p.L550= (on ENST00000510661; = p.L916= on NM_001013627.2) | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as COSV65453542; called by muse, mutect2, varscan2
- NMNAT3 | c.252G>A p.E84= (on ENST00000296202 / NM_001320512.1; = p.E47= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs1449645879, COSV56156321; called by muse, mutect2, varscan2
- OR2A42 | c.306C>T p.L102= | Silent (SNP) | VAF 205/413 reads (50%) | catalogued as COSV66955710; called by muse, mutect2, varscan2
- OR51B2 | c.264G>A p.R88= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as COSV60916702; called by muse, mutect2, varscan2
- OSBP2 | c.930C>T p.S310= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV60243164; called by muse, mutect2, varscan2
- PAPPA | c.1548C>T p.F516= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100072759, COSV60283763, COSV60285609; called by muse, mutect2, varscan2
- PAPPA2 | c.2385C>T p.F795= | Silent (SNP) | VAF 79/187 reads (42%) | catalogued as COSV62778715; called by muse, mutect2, varscan2
- PIGS | c.1539C>T p.F513= | Silent (SNP) | VAF 79/181 reads (44%) | catalogued as rs757417864, COSV52024564; called by muse, mutect2, varscan2
- PIK3AP1 | c.840G>A p.V280= | Silent (SNP) | VAF 73/140 reads (52%) | catalogued as COSV59532713; called by muse, mutect2, varscan2
- PYROXD2 | c.939G>A p.K313= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as rs1315766442, COSV65329841; called by muse, mutect2, varscan2
- RFX5 | c.669C>T p.I223= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as rs778840668, COSV51839305; called by muse, mutect2, varscan2
- RLN3 | c.297C>T p.A99= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as COSV54600864; called by muse, mutect2, varscan2
- RPP21 | c.477C>T p.S159= (on ENST00000428040; = p.S136= on NM_024839.4) | Silent (SNP) | VAF 181/236 reads (77%) | catalogued as COSV64955446; called by muse, mutect2, varscan2
- SH3BP5L | c.321G>A p.G107= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV63539254; called by muse, mutect2
- SYNJ2BP | c.177C>T p.L59= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV56445716; called by muse, mutect2, varscan2
- TARBP1 | c.4056G>A p.K1352= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV50184985; called by muse, mutect2, varscan2
- TP53BP1 | c.2001C>A p.I667= | Silent (SNP) | VAF 83/203 reads (41%) | catalogued as COSV55501881; called by muse, mutect2, varscan2
- TRAK1 | c.1728C>T p.I576= (on ENST00000327628 / NM_001349247.2; = p.I518= on NM_014965.5) | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs779450702, COSV58257005; called by muse, mutect2, varscan2
- ZKSCAN7 | c.660T>G p.T220= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99837383; called by muse, mutect2
- NF2 | c.-2C>T | 5'UTR (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100097107; called by muse, varscan2
- SNAP25 | c.164-262G>A | Intron (SNP) | VAF 50/116 reads (43%) | catalogued as rs1431916684, COSV54770791; called by muse, mutect2, varscan2
